Somatic mutation profile of tumor specimen TCGA-ZB-A96R-01A (aliquot TCGA-ZB-A96R-01A-11D-A428-09) from TCGA case TCGA-ZB-A96R, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 38.3 years (13,977 days).
Specimen TCGA-ZB-A96R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af0ef62c-17db-46a3-8afa-abfd1998d146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96R-10A (Blood Derived Normal), aliquot TCGA-ZB-A96R-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09fab050-6798-425d-9dde-0aa9c12f7049

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SACS | c.9904C>A p.L3302I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV66544118; called by muse, mutect2
- STIL | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV54550463; called by muse, mutect2
- LTB4R | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNRPD2 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
